CCDI case PBBYKX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/556b44b0-0686-403b-a855-ab562f02ae74

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Pleomorphic xanthoastrocytoma: ICD-O-3 morphology code: 9424/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.2 years (4,080 days).

Biospecimens (3 samples)
- Sample 0DNGGB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNGGJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNGGT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
